Somatic mutation profile of tumor specimen MMRF_1354_2_BM_CD138pos (aliquot MMRF_1354_2_BM_CD138pos_T1_KBS5U_L05835) from MMRF case MMRF_1354, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.4 years (27,527 days).
Specimen MMRF_1354_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 670f737d-8b46-46a5-9b56-156eca6d1f2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1354_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1354_1_PB_Whole_C2_KAS5U_L00649; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ec21cf6-43b4-47ee-8dbf-59c53033bd1c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCCC2 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as CM126864, COSV60154275; called by muse, mutect2
- URB1 | c.2106+1G>A p.X702_splice | Splice Site (SNP) | VAF 4/94 reads (4%) | catalogued as rs956463531; called by muse, mutect2
- XDH | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV101051869; called by muse, mutect2
- ELAVL2 | chr9:23690421 A>C | 3'Flank (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- KCNC1 | c.*2305C>A | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
